MMRF case MMRF_1555 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fc104d34-4258-4d93-841e-9196318c2a88

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Dead; Days to death: 469 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.2 years (30,380 days); ISS stage: III; Days to last known disease status: 469 days (1.3 years); Days to last follow up: 469 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 47 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 130 days; Days to treatment end: 230 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 248 days; Days to treatment end: 340 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 469.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 1): M Protein 3.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.315 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 56.3 mg/dL; Immunoglobulin G 60.8 g/L; Immunoglobulin A 0.185 g/L; Immunoglobulin M 0.126 g/L; Beta 2 Microglobulin 6.8 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 10.2 g/dL; Glucose 4.84 mmol/L.
- Day 99 (ECOG 1): M Protein 3.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.315 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 40 mg/dL; Immunoglobulin G 48.5 g/L; Immunoglobulin A 0.114 g/L; Immunoglobulin M 0.148 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 9.5 g/dL; Glucose 5.56 mmol/L.
- Day 186: M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.406 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 30.2 mg/dL; Immunoglobulin G 20.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 0.7 µg/mL; Hemoglobin 5.15 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 213 ×10⁹/L.
- Day 239 (ECOG 1): M Protein 2.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 39.8 mg/dL; Immunoglobulin G 24.2 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 6.99 mmol/L.
- Day 344 (ECOG 1): M Protein 4.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 150 mg/dL; Immunoglobulin G 60.6 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 26 g/L; Total Protein 9.9 g/dL; Glucose 7.21 mmol/L.

Other clinical attributes
- Day -27: Weight: 50 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1555_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1555_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
